Somatic mutation profile of tumor specimen C3L-01664-01 (aliquot CPT0086490009) from CPTAC case C3L-01664, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 75.6 years (27,611 days).
Specimen C3L-01664-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb4c1be9-4d09-412f-992c-a6ddb51461d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01664-31 (Blood Derived Normal), aliquot CPT0087420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9994c8a2-5f52-4cb2-ab15-2fd9582eb98d

The open-access MAF lists 248 somatic variants for this specimen: 174 protein-altering or splice-affecting, 54 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 54, Frame Shift Del 24, Intron 13, Splice Site 6, Nonsense Mutation 6, Frame Shift Ins 5, Splice Region 4, 5'UTR 3, In Frame Del 3, 3'UTR 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 60/566 reads (11%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3R1 | c.1365_1370del p.F456_Q457del (on ENST00000521381 / NM_181523.3; = p.F186_Q187del on NM_181504.4) | In Frame Del (DEL) | VAF 8/31 reads (26%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 73/244 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM30 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.168); catalogued as rs763441999; called by muse, mutect2, varscan2
- ADAMTS14 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 51/126 reads (40%) | catalogued as rs1564549162; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.143A>G p.N48S | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs147771998; called by muse, mutect2, varscan2
- ALDH5A1 | c.1307A>G p.H436R | Missense Mutation (SNP) | VAF 135/384 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62374556; called by muse, mutect2, varscan2
- ARHGEF12 | c.2433A>C p.Q811H | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs1429583586; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 31/152 reads (20%) | catalogued as rs768244116; called by mutect2, varscan2
- C19orf47 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs534758453, COSV63510823; called by muse, mutect2, varscan2
- CDT1 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 85/341 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs752730813, COSV99967108; called by muse, mutect2, varscan2
- CEACAM6 | c.64+2T>C p.X22_splice | Splice Site (SNP) | VAF 9/45 reads (20%) | catalogued as rs1555820929; called by muse, mutect2, varscan2
- CHD4 | c.218del p.K73Rfs*129 | Frame Shift Del (DEL) | VAF 25/161 reads (16%) | catalogued as rs1322050057; called by mutect2, pindel, varscan2
- CHD6 | c.4760G>A p.G1587D | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64693783; called by muse, mutect2, varscan2
- COL6A3 | c.1868C>A p.P623H | Missense Mutation (SNP) | VAF 176/435 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV55086064; called by muse, mutect2, varscan2
- CSPG4 | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as rs1490613821; called by muse, mutect2, varscan2
- CTNS | c.1048T>C p.F350L | Missense Mutation (SNP) | VAF 98/936 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1220760004; called by muse, mutect2
- DGKH | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.792); catalogued as rs1402257049; called by muse, mutect2, varscan2
- DLGAP3 | c.2198C>T p.T733M | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1217266034, COSV99029982; called by muse, mutect2, varscan2
- DNAH3 | c.10438C>T p.R3480W | Missense Mutation (SNP) | VAF 145/349 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761505991, COSV99764969; called by muse, mutect2, varscan2
- ECE1 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs185424269; called by muse, mutect2, varscan2
- EDRF1 | c.3249_3250del p.R1083Sfs*5 (on ENST00000356792 / NM_001202438.2; = p.R1049Sfs*5 on NM_015608.2) | Frame Shift Del (DEL) | VAF 106/550 reads (19%) | catalogued as rs1163175880; called by pindel, varscan2
- EPB41L4A | c.885del p.F295Lfs*35 | Frame Shift Del (DEL) | VAF 30/73 reads (41%) | catalogued as rs1157347372; called by mutect2, pindel
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 24/248 reads (10%) | catalogued as rs774060142; called by mutect2, pindel
- FMN1 | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs917840063; called by muse, mutect2, varscan2
- GC | c.818G>A p.C273Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764464348; called by muse, mutect2, varscan2
- GPBP1 | c.66G>A p.S22= | Splice Region (SNP) | VAF 15/80 reads (19%) | catalogued as rs369233611; called by muse, mutect2
- GRIA3 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.372); catalogued as rs1183014762; called by muse, mutect2, varscan2
- GSE1 | c.3130+5T>C | Splice Region (SNP) | VAF 31/233 reads (13%) | catalogued as COSV99497327; called by muse, mutect2, varscan2
- GUSB | c.1634C>T p.T545M | Missense Mutation (SNP) | VAF 120/627 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1283774245; called by muse, mutect2, varscan2
- GZMB | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 157/417 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs751052963, COSV53543595; called by muse, mutect2, varscan2
- HS6ST1 | c.199_201del p.K67del | In Frame Del (DEL) | VAF 108/575 reads (19%) | catalogued as rs1385271389; called by pindel, varscan2
- HTR1B | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 80/199 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199934430, COSV64051046; called by muse, mutect2, varscan2
- INPP5B | c.2627-2dup p.X876_splice (on ENST00000373023; = p.X796_splice on NM_005540.3 and 3 other RefSeq transcripts) | Splice Site (INS) | VAF 64/198 reads (32%) | catalogued as rs35888275; called by mutect2, pindel, varscan2
- IRF8 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV51898699; called by muse, mutect2
- IRX1 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs760388504, COSV57358381, COSV57358629; called by muse, mutect2, varscan2
- JPT1 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs764477731, COSV55470736; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 49/144 reads (34%) | catalogued as COSV65473126, COSV65473260; called by mutect2, varscan2
- MSANTD4 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as rs761212531, COSV100108616; called by muse, mutect2, varscan2
- MTNR1B | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 89/217 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763511406, COSV57066837, COSV57069785; called by muse, mutect2, varscan2
- MUC12 | c.2489C>T p.T830M (on ENST00000379442; = p.T687M on NM_001164462.1) | Missense Mutation (SNP) | VAF 84/2262 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs562126852; called by muse, mutect2
- NCOR2 | c.4502G>A p.R1501H | Missense Mutation (SNP) | VAF 46/269 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753887869; called by muse, mutect2, varscan2
- NCR3 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as COSV99279043; called by muse, mutect2, varscan2
- NFE2L3 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs895347796; called by muse, mutect2, varscan2
- NPIPB6 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 22/514 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.964); catalogued as rs766471295; called by muse, mutect2
- NRIP1 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.173); catalogued as COSV59660503, COSV59661364; called by muse, mutect2, varscan2
- NRXN2 | c.3982G>A p.D1328N | Missense Mutation (SNP) | VAF 194/541 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1018924695, COSV55450521; called by muse, mutect2, varscan2
- NWD1 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs752846876; called by muse, mutect2, varscan2
- OR10H5 | c.708C>A p.N236K | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.158); catalogued as COSV58277382; called by muse, mutect2, varscan2
- PARP10 | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs782360810, COSV57297284; called by muse, mutect2, varscan2
- PCARE | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 68/186 reads (37%) | catalogued as rs1439930038, CM1511739, COSV59057907; called by muse, mutect2, varscan2
- PCDHB10 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 96/662 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.977); catalogued as COSV53377466; called by muse, varscan2
- PCIF1 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.288); catalogued as rs756316870; called by muse, mutect2, varscan2
- PDCD6 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); catalogued as rs1407999951; called by muse, mutect2
- PFKP | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 102/308 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs762200045, COSV66897719, COSV66901885; called by muse, mutect2, varscan2
- PHKA2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs777332060, COSV66054619; called by muse, mutect2, varscan2
- PLAG1 | c.551del p.K184Sfs*45 | Frame Shift Del (DEL) | VAF 145/632 reads (23%) | catalogued as rs141930943; called by mutect2, pindel, varscan2
- PLEKHM2 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 85/272 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs764035629; called by muse, mutect2, varscan2
- PPFIBP2 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV55078232; called by muse, mutect2
- PPT2 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 62/321 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs766967673; called by muse, mutect2, varscan2
- PRR23A | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as rs1283582184; called by muse, mutect2
- PSMA7 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 75/306 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs1300556692, COSV100064516; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 44/108 reads (41%) | catalogued as rs146650273; called by pindel, varscan2
- PTPRT | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 82/303 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.28); catalogued as rs778928297, COSV61977204; called by muse, mutect2, varscan2
- REPIN1 | c.1116del p.S373Pfs*242 | Frame Shift Del (DEL) | VAF 24/50 reads (48%) | catalogued as rs759247453; called by mutect2, varscan2
- RERE | c.3249del p.S1084Rfs*173 | Frame Shift Del (DEL) | VAF 28/88 reads (32%) | catalogued as rs745806637; ClinVar: uncertain significance; called by pindel, varscan2
- RFX4 | c.523G>A p.G175R (on ENST00000392842 / NM_213594.3; = p.G81R on NM_032491.6) | Missense Mutation (SNP) | VAF 159/450 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57583296; called by muse, mutect2, varscan2
- RNF17 | c.3736C>T p.R1246C | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55042018; called by muse, mutect2, varscan2
- ROBO2 | c.3233del p.P1078Qfs*95 | Frame Shift Del (DEL) | VAF 40/206 reads (19%) | catalogued as rs745519558, COSV100168583; called by mutect2, varscan2
- RPL12 | c.492+1G>A p.X164_splice | Splice Site (SNP) | VAF 14/67 reads (21%) | catalogued as rs1286691465; called by muse, mutect2, varscan2
- RRAGA | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 110/307 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100998149; called by muse, mutect2, varscan2
- RTF2 | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50128087; called by muse, mutect2, varscan2
- SF3B1 | c.3233T>G p.V1078G | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV59225354; called by muse, mutect2, varscan2
- SHISA9 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.615); catalogued as rs1422899589; called by muse, mutect2
- SOAT2 | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV56858546; called by muse, mutect2
- SOBP | c.2428G>A p.A810T | Missense Mutation (SNP) | VAF 91/538 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.949); catalogued as rs755690013, COSV57998129; called by muse, mutect2, varscan2
- SPEF2 | c.3778G>C p.A1260P | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs760740790; called by muse, mutect2, varscan2
- SRRM1 | c.2311G>A p.V771I | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs761948922, COSV60478311; called by muse, mutect2, varscan2
- SV2C | c.1205G>A p.W402* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100456428; called by muse, mutect2, varscan2
- SZT2 | c.9892C>T p.R3298C (on ENST00000634258 / NM_001365999.1; = p.R3241C on NM_015284.4) | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs764177776, COSV65094335; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TENM3 | c.7444G>A p.G2482S | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs909066766; called by muse, mutect2, varscan2
- TJAP1 | c.1393G>A p.E465K (on ENST00000372445 / NM_001146016.1; = p.E455K on NM_080604.3) | Missense Mutation (SNP) | VAF 52/349 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as rs766044760, COSV52499143; called by muse, mutect2, varscan2
- TTBK1 | c.1316del p.P439Qfs*16 | Frame Shift Del (DEL) | VAF 21/74 reads (28%) | catalogued as COSV104389590; called by mutect2, pindel, varscan2
- TTLL6 | c.1097C>T p.S366L (on ENST00000393382 / NM_001130918.3; = p.S59L on NM_173623.3) | Missense Mutation (SNP) | VAF 121/291 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs762249687; called by muse, mutect2, varscan2
- UGT1A9 | c.364dup p.S122Ffs*8 | Frame Shift Ins (INS) | VAF 28/93 reads (30%) | catalogued as rs773627969; called by mutect2, varscan2
- UNC79 | c.6305C>T p.T2102M (on ENST00000393151 / NM_001346218.2; = p.T1925M on NM_020818.5) | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs139549696; called by muse, mutect2, varscan2
- YIF1A | c.391del p.R131Gfs*50 | Frame Shift Del (DEL) | VAF 87/254 reads (34%) | catalogued as rs761507279; called by mutect2, pindel, varscan2
- ZBTB5 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs754674198, COSV100312697; called by muse, mutect2, varscan2
- ZC3H13 | c.1586A>G p.Y529C | Missense Mutation (SNP) | VAF 35/277 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1566207754, COSV54451383; called by muse, mutect2, varscan2
- ZMAT3 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 195/560 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373375357; called by muse, mutect2, varscan2
- ZNF513 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 153/837 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1409868479; called by muse, mutect2, varscan2
- ZNF629 | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.056); catalogued as rs1266997274; called by muse, mutect2, varscan2
- ABCC12 | c.2051C>T p.T684I | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- ACTB | c.175_187delinsT p.Q59_G63delinsC | In Frame Del (DEL) | VAF 90/459 reads (20%) | called by pindel, varscan2*
- ANKFN1 | c.24G>A p.R8= | Splice Region (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- ARF1 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 54/297 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AVEN | c.212C>A p.A71D | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- BUB1B | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 88/661 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C2CD4B | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CACNA1G | c.4709T>C p.L1570P | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- CAPNS1 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.92); called by muse, mutect2
- CHST5 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CLK4 | c.578dup p.N193Kfs*7 | Frame Shift Ins (INS) | VAF 46/148 reads (31%) | called by mutect2, pindel, varscan2
- CLOCK | c.725G>T p.R242M | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CLSPN | c.78T>G p.S26R | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- COL19A1 | c.2383G>T p.G795* | Nonsense Mutation (SNP) | VAF 21/143 reads (15%) | called by muse, mutect2, varscan2
- COL9A3 | c.738G>A p.R246= | Splice Region (SNP) | VAF 58/259 reads (22%) | called by muse, mutect2, varscan2
- CSNK1A1L | c.590A>C p.E197A | Missense Mutation (SNP) | VAF 119/304 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYRIA | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.72); called by muse, varscan2
- DCHS2 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- DNAH1 | c.12262T>C p.S4088P | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- DNAH14 | c.4772A>G p.D1591G (on ENST00000445597; = p.D1996G on NM_001367479.1) | Missense Mutation (SNP) | VAF 57/331 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DND1 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 94/532 reads (18%) | called by muse, mutect2, varscan2
- DOK3 | c.805del p.L269Cfs*45 | Frame Shift Del (DEL) | VAF 18/79 reads (23%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 123/382 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- EGLN3 | c.436A>G p.I146V | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ENO3 | c.1017_1023del p.L340* | Frame Shift Del (DEL) | VAF 81/323 reads (25%) | called by mutect2, pindel, varscan2
- EXOC8 | c.1591C>A p.Q531K | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.857); called by muse, mutect2
- FAM149B1 | c.964C>T p.H322Y | Missense Mutation (SNP) | VAF 93/299 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.055); called by muse, varscan2
- FLG | c.7399G>T p.G2467W | Missense Mutation (SNP) | VAF 163/954 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- FLG | c.1910G>T p.W637L | Missense Mutation (SNP) | VAF 278/1504 reads (18%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- FLG2 | c.6657G>T p.Q2219H | Missense Mutation (SNP) | VAF 123/514 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- FMNL1 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 63/171 reads (37%) | called by muse, mutect2, varscan2
- FOXR1 | c.182T>C p.I61T | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- FUBP3 | c.1121del p.X374_splice | Splice Site (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- GAPDH | c.523A>G p.M175V | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); called by muse, mutect2
- GJA8 | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 29/664 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.321); called by muse, mutect2
- GRK6 | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GTF2H3 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 69/404 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HP1BP3 | c.1036A>T p.I346F | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IGDCC3 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INTS6 | c.2543dup p.L848Ffs*6 | Frame Shift Ins (INS) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
- JAG1 | c.3230del p.L1077* | Frame Shift Del (DEL) | VAF 178/373 reads (48%) | called by mutect2, pindel, varscan2
- JCAD | c.2029C>A p.H677N | Missense Mutation (SNP) | VAF 57/320 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KDM2B | c.2603del p.K868Sfs*66 | Frame Shift Del (DEL) | VAF 29/177 reads (16%) | called by mutect2, pindel, varscan2
- LGALS12 | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- MACROH2A2 | c.977C>A p.A326E | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MATR3 | c.1566A>T p.K522N | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ME3 | c.731T>C p.I244T | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MINPP1 | c.870T>A p.F290L | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- MMP19 | c.644dup p.H216Pfs*27 | Frame Shift Ins (INS) | VAF 68/320 reads (21%) | called by mutect2, pindel, varscan2
- MMS22L | c.2981_2982del p.I994Tfs*34 | Frame Shift Del (DEL) | VAF 35/82 reads (43%) | called by mutect2, pindel, varscan2
- MTOR | c.3416_3417del p.V1139Gfs*11 | Frame Shift Del (DEL) | VAF 20/111 reads (18%) | called by pindel, varscan2
- MYH13 | c.3161G>A p.R1054K | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MYO1H | c.2867A>G p.H956R | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOTCH1 | c.4133T>C p.F1378S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- NUP153 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- NUP160 | c.3959C>A p.P1320H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.495); called by muse, varscan2
- NXF1 | c.1457A>G p.Q486R | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- OR5K3 | c.232A>G p.T78A | Missense Mutation (SNP) | VAF 79/185 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PARPBP | c.56del p.N19Ifs*47 | Frame Shift Del (DEL) | VAF 35/206 reads (17%) | called by mutect2, pindel, varscan2
- PNMA8B | c.1435T>C p.Y479H | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRKG1 | c.1067C>G p.A356G | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- PYCR1 | c.323T>A p.L108Q | Missense Mutation (SNP) | VAF 123/348 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROBO2 | c.1052G>C p.G351A | Missense Mutation (SNP) | VAF 153/432 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RSKR | c.1112A>G p.K371R | Missense Mutation (SNP) | VAF 20/440 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.877); called by muse, mutect2
- RSRC2 | c.955_956del p.N319Pfs*5 | Frame Shift Del (DEL) | VAF 154/508 reads (30%) | called by mutect2, pindel, varscan2
- SEC24C | c.2042A>G p.Q681R | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SEMA3F | c.274-1_274del p.X92_splice | Splice Site (DEL) | VAF 118/307 reads (38%) | called by mutect2, pindel, varscan2
- SPATA22 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SPRED1 | c.459G>T p.K153N | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SUDS3 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- TAF3 | c.52T>G p.C18G | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D9B | c.2955G>T p.E985D (on ENST00000356834 / NM_198868.3; = p.E968D on NM_015043.4) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.071); called by muse, varscan2
- TIMM8A | c.132+2T>C p.X44_splice | Splice Site (SNP) | VAF 186/304 reads (61%) | called by muse, mutect2, varscan2
- TRAPPC11 | c.1391A>C p.Y464S | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TSPOAP1 | c.852G>T p.Q284H | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- TTN | c.62929G>A p.A20977T (on ENST00000591111; = p.A13553T on NM_003319.4) | Missense Mutation (SNP) | VAF 114/292 reads (39%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VWA3A | c.36dup p.A13Cfs*7 | Frame Shift Ins (INS) | VAF 37/108 reads (34%) | called by mutect2, pindel, varscan2
- ZBED9 | c.766G>T p.V256L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ZDHHC21 | c.494del p.K165Sfs*15 | Frame Shift Del (DEL) | VAF 8/75 reads (11%) | called by mutect2, pindel, varscan2
- ZNF296 | c.665G>A p.S222N | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF628 | c.2207del p.P736Lfs*47 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | called by mutect2, pindel, varscan2
- ZNF774 | c.1150T>A p.F384I | Missense Mutation (SNP) | VAF 114/314 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACTN2 | c.1782C>T p.S594= | Silent (SNP) | VAF 96/1024 reads (9%) | called by muse, mutect2
- ARHGAP5 | c.2961A>T p.A987= | Silent (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- BEND3 | c.2106C>A p.P702= | Silent (SNP) | VAF 54/154 reads (35%) | called by muse, mutect2, varscan2
- BRINP2 | c.201C>T p.R67= | Silent (SNP) | VAF 54/280 reads (19%) | catalogued as rs138435872; called by muse, mutect2, varscan2
- C19orf47 | c.981G>A p.P327= | Silent (SNP) | VAF 40/142 reads (28%) | catalogued as rs201616754, COSV63511216; called by muse, mutect2, varscan2
- CCDC8 | c.666C>T p.G222= | Silent (SNP) | VAF 188/531 reads (35%) | catalogued as rs1385856223, COSV56773021; called by muse, mutect2, varscan2
- CD276 | c.1008C>T p.G336= | Silent (SNP) | VAF 24/230 reads (10%) | called by muse, mutect2
- COL5A3 | c.4380A>G p.G1460= | Silent (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- CSMD2 | c.4443C>T p.Y1481= | Silent (SNP) | VAF 76/195 reads (39%) | catalogued as rs142841043; called by muse, mutect2, varscan2
- CXADR | c.6G>A p.A2= | Silent (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- DMTF1 | c.420T>C p.D140= | Silent (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- ELFN1 | c.834C>T p.P278= | Silent (SNP) | VAF 32/261 reads (12%) | called by muse, mutect2, varscan2
- ELL3 | c.714A>T p.P238= | Silent (SNP) | VAF 51/153 reads (33%) | called by muse, mutect2, varscan2
- FAT1 | c.6030G>A p.E2010= | Silent (SNP) | VAF 81/219 reads (37%) | catalogued as rs371979270; called by muse, mutect2, varscan2
- FOXJ1 | c.807G>A p.R269= | Silent (SNP) | VAF 18/128 reads (14%) | called by muse, mutect2, varscan2
- GDF1 | c.465G>A p.A155= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as rs1285589631; called by muse, mutect2, varscan2
- GJD4 | c.1020G>A p.A340= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as rs755990278, COSV58703043; called by muse, mutect2, varscan2
- GRHL1 | c.1689A>G p.K563= | Silent (SNP) | VAF 34/85 reads (40%) | called by muse, mutect2, varscan2
- HBA1 | c.18C>T p.A6= | Silent (SNP) | VAF 94/1136 reads (8%) | catalogued as rs1432967763; called by muse, mutect2
- HOXC12 | c.297C>T p.C99= | Silent (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- IGFALS | c.780C>T p.G260= | Silent (SNP) | VAF 271/738 reads (37%) | catalogued as rs773461461; called by muse, mutect2, varscan2
- IL17RC | c.825G>A p.P275= (on ENST00000295981 / NM_153461.4; = p.P204= on NM_153460.4) | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs576408431; called by muse, mutect2, varscan2
- IRX2 | c.1129C>T p.L377= | Silent (SNP) | VAF 32/233 reads (14%) | called by muse, mutect2, varscan2
- KCNC3 | c.756C>T p.G252= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as rs1027908918; called by muse, mutect2, varscan2
- KCNT1 | c.1173G>A p.T391= (on ENST00000488444; = p.T410= on NM_020822.3) | Silent (SNP) | VAF 30/128 reads (23%) | catalogued as rs778178642, COSV53703072; called by muse, mutect2, varscan2
- KIR3DL2 | c.201C>T p.H67= | Silent (SNP) | VAF 212/536 reads (40%) | catalogued as rs766660967; called by muse, mutect2, varscan2
- LRRN4 | c.1248G>A p.T416= | Silent (SNP) | VAF 34/274 reads (12%) | catalogued as rs1183341171; called by muse, mutect2, varscan2
- MAGEB5 | c.720G>A p.L240= | Silent (SNP) | VAF 13/170 reads (8%) | called by muse, mutect2
- MCL1 | c.897A>C p.V299= | Silent (SNP) | VAF 105/383 reads (27%) | called by muse, mutect2, varscan2
- MTHFD2L | c.778C>T p.L260= (on ENST00000395759 / NM_001144978.2; = p.L202= on NM_001004346.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as rs748527979; called by muse, mutect2, varscan2
- NT5E | c.1287C>T p.S429= | Silent (SNP) | VAF 33/754 reads (4%) | called by muse, mutect2
- NUP160 | c.3903C>A p.V1301= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs1247647329; called by muse, varscan2
- OBSL1 | c.2895C>T p.S965= | Silent (SNP) | VAF 25/246 reads (10%) | catalogued as rs377130755; called by muse, mutect2, varscan2
- OR4L1 | c.709C>T p.L237= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV59851307; called by muse, mutect2, varscan2
- PCDH8 | c.777G>A p.A259= | Silent (SNP) | VAF 58/184 reads (32%) | catalogued as rs1346124014; called by muse, mutect2, varscan2
- PEX5 | c.1800G>A p.S600= (on ENST00000420616; = p.S592= on NM_000319.5) | Silent (SNP) | VAF 283/720 reads (39%) | catalogued as rs370306007; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- PIKFYVE | c.1569C>T p.N523= | Silent (SNP) | VAF 84/506 reads (17%) | catalogued as rs199728281; called by muse, mutect2, varscan2
- PML | c.1509G>T p.R503= | Silent (SNP) | VAF 55/491 reads (11%) | called by muse, mutect2, varscan2
- PNPLA6 | c.1047G>A p.L349= (on ENST00000414982 / NM_001166111.2; = p.L301= on NM_006702.5) | Silent (SNP) | VAF 45/335 reads (13%) | called by muse, mutect2, varscan2
- PRSS27 | c.111C>T p.G37= | Silent (SNP) | VAF 41/100 reads (41%) | called by muse, mutect2, varscan2
- PTGDR | c.738G>A p.P246= | Silent (SNP) | VAF 54/143 reads (38%) | catalogued as rs201775752; called by muse, mutect2, varscan2
- RRM2 | c.1152C>A p.T384= | Silent (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- SAYSD1 | c.273G>C p.S91= | Silent (SNP) | VAF 86/212 reads (41%) | called by muse, mutect2, varscan2
- SLC2A8 | c.1122C>T p.A374= | Silent (SNP) | VAF 24/169 reads (14%) | catalogued as rs376139497; called by muse, mutect2, varscan2
- SPON2 | c.529C>A p.R177= | Silent (SNP) | VAF 58/163 reads (36%) | catalogued as rs764512800; called by muse, mutect2, varscan2
- SUPT16H | c.2616C>T p.N872= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs139275142; called by muse, mutect2, varscan2
- SYTL2 | c.1140C>T p.D380= | Silent (SNP) | VAF 54/172 reads (31%) | catalogued as rs1027567562; called by muse, mutect2, varscan2
- TMEM86A | c.108G>A p.S36= | Silent (SNP) | VAF 137/417 reads (33%) | catalogued as rs779125899; called by muse, mutect2, varscan2
- TNN | c.471C>T p.C157= | Silent (SNP) | VAF 42/231 reads (18%) | catalogued as COSV99512315; called by muse, mutect2, varscan2
- TSPEAR | c.129C>T p.G43= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs782142824, COSV59960896; called by muse, mutect2, varscan2
- UBQLN4 | c.363C>T p.P121= | Silent (SNP) | VAF 36/179 reads (20%) | called by muse, mutect2, varscan2
- URB1 | c.828G>A p.S276= | Silent (SNP) | VAF 43/162 reads (27%) | catalogued as rs192355871, COSV100784021, COSV63220763; called by muse, mutect2, varscan2
- WHRN | c.1596C>T p.H532= | Silent (SNP) | VAF 150/387 reads (39%) | catalogued as rs775240892; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF469 | c.4887G>A p.T1629= (on ENST00000437464; = p.T1657= on NM_001367624.2) | Silent (SNP) | VAF 111/254 reads (44%) | catalogued as rs769603060; called by muse, mutect2, varscan2
- BTNL10 | n.289G>A | RNA (SNP) | VAF 213/357 reads (60%) | called by muse, mutect2, varscan2
- CACNB4 | c.1116+19del | Intron (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel
- DMTN | c.*855del | 3'UTR (DEL) | VAF 7/45 reads (16%) | catalogued as rs1300307029; called by mutect2, pindel
- DNAAF3 | c.86-68del | Intron (DEL) | VAF 104/634 reads (16%) | called by pindel, varscan2
- ETNK1 | c.-144G>A | 5'UTR (SNP) | VAF 28/257 reads (11%) | called by muse, mutect2, varscan2
- GFM1 | c.689+878A>G | Intron (SNP) | VAF 109/344 reads (32%) | catalogued as rs1014396205; called by muse, mutect2, varscan2
- IFT27 | c.352+27C>T | Intron (SNP) | VAF 187/536 reads (35%) | called by muse, mutect2, varscan2
- LYRM4 | c.208-3914C>T | Intron (SNP) | VAF 24/61 reads (39%) | catalogued as rs1352047710; called by muse, mutect2, varscan2
- MAPKAP1 | c.1346-2889G>T | Intron (SNP) | VAF 32/206 reads (16%) | called by muse, mutect2, varscan2
- NAPA | c.561+148del | Intron (DEL) | VAF 21/144 reads (15%) | catalogued as rs1349876274; called by mutect2, pindel, varscan2
- NRG1 | c.701-4833del | Intron (DEL) | VAF 33/148 reads (22%) | catalogued as rs3832550; called by mutect2, varscan2
- NUCB1 | c.758-28A>C | Intron (SNP) | VAF 41/182 reads (23%) | called by muse, mutect2, varscan2
- PCMT1 | c.335-516G>A | Intron (SNP) | VAF 36/77 reads (47%) | catalogued as rs911693052; called by muse, mutect2, varscan2
- PNPLA2 | c.920-39G>A | Intron (SNP) | VAF 32/83 reads (39%) | catalogued as rs547562607; called by muse, mutect2, varscan2
- PRCD | chr17:76545218 G>A | 3'Flank (SNP) | VAF 187/594 reads (31%) | called by muse, mutect2, varscan2
- RORA | c.197-61114C>T | Intron (SNP) | VAF 69/190 reads (36%) | called by muse, mutect2, varscan2
- SCN4B | c.*2050_*2052del | 3'UTR (DEL) | VAF 60/382 reads (16%) | called by pindel, varscan2
- SNED1 | c.-46A>G | 5'UTR (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- TNFRSF14 | c.-116T>A | 5'UTR (SNP) | VAF 122/306 reads (40%) | called by muse, mutect2, varscan2
- ZMYND8 | c.26-8901G>T | Intron (SNP) | VAF 13/170 reads (8%) | called by muse, mutect2
